Gene-level copy-number profile of tumor specimen C3N-02768-01 (profiled together with C3N-02768-02) from CPTAC case C3N-02768, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 46.6 years (17,037 days).
Specimen C3N-02768-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ae522fe1-dc06-4eba-afea-fb6ad164da7f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02768-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/1731e8dd-5f23-4dc0-833f-a8424c4d6f06

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 525; copy number 1: 915; copy number 2: 9,926; copy number 3: 22,379; copy number 4: 19,226; copy number 5: 5,620; copy number 6: 68; copy number 7: 132; copy number 8: 5; copy number 9: 57; copy number 12: 10; copy number 14: 35; copy number 16: 12; copy number 32: 3.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,966,929–21,967,751, 1 gene (within-gene range 0–2): CDKN2A-DT.
- chr9:22,046,758–22,046,901, 1 gene (within-gene range 0–2): AL354709.1.
- chr9:95,065,350–95,086,094, 5 genes (within-gene range 0–2): MIR6081, MIR23B, MIR27B, MIR3074, MIR24-1.
- chr9:95,113,708–95,142,541, 3 genes (within-gene range 0–2): AL354893.2, AL354893.1, RNA5SP288.
- chr21:44,107,373–44,210,114, 5 genes (within-gene range 0–2): PWP2, GATD3A, LINC01678, AP001056.2, AP001056.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 254 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:60,281,444–60,546,660, 1 gene, copy number 8: AC244258.1.
- chr8:126,325,454–130,655,712, 57 genes, copy number 9: AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, LINC00824, CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686, MTRF1LP2, GSDMC, AC022973.5, CYRIB, AC022973.2, AC022973.1, AC022973.4, AC022973.3, AC131568.1, RNU7-181P, MIR5194, ASAP1, RNU6-1255P, ASAP1-IT2, AC103725.1, AC009682.1, AC139019.1, AC090987.1.
- chr8:145,002,811–145,066,685, 4 genes, copy number 7 (within-gene range 5–7): ZNF252P-AS1, AF235103.2, AC139103.1, C8orf33.
- chr11:69,294,151–71,603,353, 60 genes, copy number 12–32 (within-gene range 3–32): MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1, ACTE1P, DHCR7, AP002387.1, NADSYN1, MIR6754, AP000867.2, KRTAP5-7, KRTAP5-8, KRTAP5-9, AP000867.5, KRTAP5-10, AP000867.1, KRTAP5-11, KRTAP5-14P, OR7E87P.
- chr14:18,333,726–18,419,273, 4 genes, copy number 8: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr16:46,469,341–46,575,094, 4 genes, copy number 7: ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1.
- chr17:28,041,737–28,196,381, 1 gene, copy number 7 (within-gene range 4–7): NLK.
- chr17:28,116,239–30,108,452, 123 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 78. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
